Gene-level copy-number profile of tumor specimen TCGA-MA-AA41-01A from TCGA case TCGA-MA-AA41, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 33.9 years (12,398 days).
Specimen TCGA-MA-AA41-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.efcfe9c4-debe-4e3a-a606-d11f85ee7a4c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MA-AA41-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44246fdf-cfa9-41f1-82c0-cf45463ff92e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,163; copy number 2: 38,347; copy number 3: 12,471; copy number 4: 3,305; copy number 5: 18; copy number 6: 435; copy number 8: 6; copy number 9: 30; copy number 13: 5; copy number 24: 22; copy number 34: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MA-AA41-01A-11D-A386-01): tumor purity 0.72, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 515 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:524,012–846,561, 3 genes, copy number 5 (within-gene range 1–5): AC087428.1, LINC01266, RPSAP32.
- chr3:114,314,501–114,529,452, 4 genes, copy number 6 (within-gene range 4–6): AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5.
- chr4:12,223,445–12,641,009, 4 genes, copy number 6: LINC02270, RNU6-578P, ECM1P2, AC093809.1.
- chr4:65,319,563–66,329,377, 11 genes, copy number 6 (within-gene range 3–9): EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A.
- chr7:52,891,837–55,433,742, 36 genes, copy number 24–34 (within-gene range 2–34): SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr9:15,553,043–16,061,663, 1 gene, copy number 6 (within-gene range 3–6): CCDC171.
- chr9:15,776,181–16,410,990, 2 genes, copy number 6: RNU6-14P, C9orf92.
- chr9:131,725,168–132,079,867, 5 genes, copy number 13: RN7SL328P, EIF4A1P3, AL160271.1, AL160271.2, MED27.
- chr17:62,626,031–77,884,119, 449 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
